Gene-level copy-number profile of tumor specimen TCGA-67-6217-01A from TCGA case TCGA-67-6217, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.7 years (26,920 days).
Specimen TCGA-67-6217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.776c7661-84db-4b5e-a1ad-206f1818f185.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-67-6217-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a4f16060-1def-4cef-bfd9-6907035e35aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 24,239; copy number 2: 24,753; copy number 3: 9,479; copy number 4: 1,207; copy number 5: 67; copy number 6: 52; copy number 9: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-67-6217-01A-11D-1752-01): tumor purity 0.25, ploidy 6.17, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 142 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,487,589–31,704,319, 12 genes, copy number 5: AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1.
- chr7:47,956,793–48,647,497, 6 genes, copy number 5 (within-gene range 3–5): AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13.
- chr8:90,198,389–90,985,238, 10 genes, copy number 5 (within-gene range 2–5): AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88.
- chr14:27,258,717–27,845,286, 3 genes, copy number 5: AL390334.1, LINC00645, MIR3171.
- chr14:31,925,801–38,041,442, 111 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,296. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
